BEATAML1.0 case 2113 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/e05e93a2-b5f3-4b85-933f-1818d9f58b91

Demographics
Sex at birth: male.

Diagnoses (1)
1. Blastic plasmacytoid dendritic cell neoplasm: ICD-O-3 morphology code: 9727/3; Tissue or organ of origin: Bone marrow; Progression or recurrence: no; ELN risk classification: Intermediate.

Biospecimens (1 sample)
- Sample BA2699D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
